Somatic mutation profile of tumor specimen 0DL1TO from CCDI case PBBYXM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Rhabdomyosarcoma, NOS; Tissue or organ of origin: Other specified parts of female genital organs; Age at diagnosis: 3.1 years (1,129 days).
Specimen 0DL1TO: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09ac20d4-ae58-4d8f-b444-2cf50c057365.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL1T2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b04dc5f-d82e-4abb-9cdf-49a1117f9d2d

The open-access MAF lists 29 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 6, Intron 3, 3'UTR 2, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 440/482 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DCAF12L2 | c.1024C>T p.R342W | Missense Mutation (SNP) | VAF 213/503 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs1169968076; called by muse, mutect2, varscan2
- EIF4G3 | c.2501G>A p.R834Q | Missense Mutation (SNP) | VAF 562/1338 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs761501966, COSV51680733; called by muse, mutect2, varscan2
- FHDC1 | c.17G>A p.C6Y | Missense Mutation (SNP) | VAF 444/1170 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52604084; called by muse, mutect2, varscan2
- KNDC1 | c.3742C>T p.R1248C | Missense Mutation (SNP) | VAF 52/671 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs896116405; called by muse, mutect2
- NDST2 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 272/721 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752636610, COSV55214661; called by muse, mutect2, varscan2
- NTRK3 | c.1250C>T p.P417L | Missense Mutation (SNP) | VAF 602/1395 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs1442871238, COSV100448123, COSV58120910; called by muse, mutect2, varscan2
- OR5C1 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 79/534 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs145416993; called by muse, mutect2, varscan2
- POLE | c.3959G>A p.R1320Q | Missense Mutation (SNP) | VAF 182/805 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs772663586; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTL6B | c.104C>A p.A35D | Missense Mutation (SNP) | VAF 211/594 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ATP6V1B2 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 83/807 reads (10%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); called by muse, mutect2
- ITGB1BP2 | c.431G>C p.R144P | Missense Mutation (SNP) | VAF 366/909 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NRK | c.2809G>T p.E937* | Nonsense Mutation (SNP) | VAF 454/1009 reads (45%) | called by muse, mutect2, varscan2
- RBM10 | c.1063-15_1092del p.X355_splice | Splice Site (DEL) | VAF 118/302 reads (39%) | called by mutect2, varscan2
- RNF32 | c.130G>C p.V44L | Missense Mutation (SNP) | VAF 299/1378 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- SGIP1 | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 401/995 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SLC15A1 | c.1973T>A p.V658D | Missense Mutation (SNP) | VAF 615/1764 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- XKR8 | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 217/585 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- GAP43 | c.432T>G p.T144= | Silent (SNP) | VAF 40/804 reads (5%) | called by muse, mutect2
- PTPRN | c.1029G>A p.A343= | Silent (SNP) | VAF 396/915 reads (43%) | catalogued as rs759978181, COSV55348458; called by muse, mutect2, varscan2
- SEMA5A | c.3030A>T p.S1010= | Silent (SNP) | VAF 339/886 reads (38%) | called by mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 41/1408 reads (3%) | called by muse, mutect2
- THBS4 | c.1041C>A p.G347= | Silent (SNP) | VAF 400/1020 reads (39%) | called by muse, mutect2, varscan2
- TMEM132B | c.3054C>A p.G1018= | Silent (SNP) | VAF 282/804 reads (35%) | called by muse, mutect2, varscan2
- AR | c.1885+3574A>G | Intron (SNP) | VAF 191/428 reads (45%) | called by muse, mutect2, varscan2
- CTAG2 | c.*146C>G | 3'UTR (SNP) | VAF 49/1183 reads (4%) | called by muse, mutect2
- ITIH4 | c.2179+12G>A | Intron (SNP) | VAF 278/708 reads (39%) | called by muse, mutect2, varscan2
- SART3 | c.1501-37G>A | Intron (SNP) | VAF 64/772 reads (8%) | called by muse, mutect2
- TECRL | c.*86C>T | 3'UTR (SNP) | VAF 69/154 reads (45%) | catalogued as COSV101168524; called by muse, mutect2, varscan2
